Somatic mutation profile of tumor specimen 0DIYSI from CCDI case PBBWFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,345 days).
Specimen 0DIYSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 775edf26-3ea2-4acd-9312-523967a53bb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIYS6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43f19c6a-e2b8-48f0-8894-8627a0ec37c7

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP1 | c.3481G>A p.V1161M (on ENST00000393609 / NM_001040118.2; = p.V916M on NM_015242.4) | Missense Mutation (SNP) | VAF 64/947 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.774); catalogued as rs752068100; called by muse, mutect2
- EVA1C | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 130/1560 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV55822968; called by muse, mutect2
- IKZF2 | c.1532G>C p.R511P | Missense Mutation (SNP) | VAF 366/1183 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs181639094; called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 64/1090 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- DSC2 | c.1329T>C p.F443= | Silent (SNP) | VAF 129/1506 reads (9%) | called by muse, mutect2
- BCORL1 | c.4306-2704G>A | Intron (SNP) | VAF 64/956 reads (7%) | catalogued as rs762735567, COSV99501140; called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 11/117 reads (9%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- SIGLEC6 | c.1012+12G>A | Intron (SNP) | VAF 86/952 reads (9%) | called by muse, mutect2
